Surgical pathology report (de-identified scan), TCGA case TCGA-60-2707, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2707-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE
- B. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE
- C. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE
- D. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE
- E. LEVEL 7 LYMPH NODE
- F. LEVEL 7 LYMPH NODE
- G. 2R RIGHT PROXIMAL PARATRACHEAL LYMPH NODE
- H. 2L LEFT PROXIMAL PARATRACHEAL LYMPH NODE
- I. 3A LYMPH NODE
- J. PLEURAL BX
- K. LEVEL 5 LYMPH NODE
- L. 12 L LYMPH NODE
- M. LEFT UPPER LOBE
- N. LEVEL 6 LYMPH NODE
- O. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

Left upper lobe lung ca.

[page 2 of 5]
[REDACTED]
[REDACTED]
FSJ: Negative for malignancy by [REDACTED]
FSM: Bronchial margin: Negative for tumor. Tissue procurement was done by [REDACTED]
called to [REDACTED]

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE

Received fresh are three pieces of gray black soft tissue measuring from 0.2 to 0.3 cm. The specimen is submitted in toto in one cassette labeled FSA.

B. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE

Received fresh are four pieces of gray black and adipose tissue measuring 0.2 cm each. The specimen is submitted in toto in one cassette labeled FSB.

C. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE

Received fresh is a single lymph node measuring 0.6 cm in diameter. The specimen is submitted in toto in one cassette labeled FSC.

D. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE

Received fresh are three pieces of adipose tissue and one presumptive lymph node. The lymph node measures 0.2 cm. The specimen is submitted in toto in one cassette labeled FSD.

E. LEVEL 7 LYMPH NODE

Received fresh are two pieces of black gray soft tissue measuring 0.2 cm each. The specimen is submitted in toto in one cassette labeled FSE.

F. LEVEL 7 LYMPH NODE

Received fresh are nine pieces of gray black soft tissue. Submitted in toto in one cassette labeled FSF.

G. 2R RIGHT PROXIMAL PARATRACHEAL LYMPH NODE

Received fresh are four pieces of pink tan soft tissue measuring 0.2 cm each. The specimen is submitted in toto in one cassette labeled FSG.

H. 2L LEFT PROXIMAL PARATRACHEAL LYMPH NODE

Received fresh are four pieces of pink tan tissue measuring less than 0.2 cm. Submitted in toto in one cassette labeled FSH.

I. 3A LYMPH NODE

Received fresh are three pieces of pink tan soft tissue measuring 0.2 cm. each. The specimen is submitted in toto in one cassette labeled FSI.

[REDACTED]

[page 3 of 5]
J. PLEURAL BIOPSY

Received fresh are four pieces of pink tan soft tissue measuring 0.2 cm each. The specimen is submitted in toto in one cassette labeled FSJ.

K. LEVEL 5 LYMPH NODE

Received fresh are four lymph nodes ranging in maximum diameter from 0.6 to 1.9 x 1.1 x 0.5 cm. They are submitted as follows:

K1: two lymph nodes

K2-K3: single lymph node in each

L. 12L LYMPH NODE

Received fresh is a single lymph node measuring 0.8 x 0.6 x 0.3 cm. It is bisected and submitted entirely in one cassette labeled L1.

M. LEFT UPPER LOBE

Received fresh is a lung lobectomy weighing 368 gm. and measuring 17.5 x 13 x 5.5 cm. The specimen has a single tumor mass with irregular border in the upper segment. The tumor measures 7.2 x 5.6 x 4.5 cm. The tumor is 2.1 cm from the bronchial margin. The tumor is grossly confined to the lung without visceral pleura invasion. The rest of the lung is congested showing focal emphysematous change. Multiple lymph nodes are found in the peribronchial region ranging in maximum diameter from 0.5 to 2.9 x 2 x 0.6 cm. All the lymph nodes are grossly negative for tumor. Representative sections submitted as follows:

FSM: bronchial margin

M2: peribronchial, lymph nodes

M3-M6: peribronchial, single lymph node in each

M7-M8: peribronchial, single lymph node

M9-M12: tumor with pleura

M13: tumor with bronchus

M14: tumor

M15-M16: random lung

N. LEVEL 6 LYMPH NODE

Received in formalin are two lymph nodes ranging in maximum diameter from 0.2 to 1.7 cm. They are grossly negative for tumor. They are submitted entirely as follows:

N1: one lymph node

N2: bisected lymph node

O. LEVEL 9 LYMPH NODE

Received fresh is a piece of fibroadipose tissue measuring 1.5 x 1 x 0.5 cm containing multiple lymph nodes. It is submitted entirely in toto in one cassette labeled O1.

[page 4 of 5]
DIAGNOSIS:

- A. LYMPH NODE, 4R DISTAL PARATRACHEAL, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- B. LYMPH NODE, 4L DISTAL PARATRACHEAL, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- C. LYMPH NODE, 4L DISTAL PARATRACHEAL, BIOPSY;
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- D. LYMPH NODE, 4L DISTAL PARATRACHEAL, BIOPSY;
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- E. LYMPH NODE, LEVEL 7, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- F. LYMPH NODE, LEVEL 7, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- G. LYMPH NODE, 2R PROXIMAL PARATRACHEAL, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- H. LYMPH NODE, 2L PROXIMAL PARATRACHEAL, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- I. LYMPH NODE, 3A, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE FRAGMENTED LYMPH NODE (0/1).
- J. PLEURA, APICAL, BIOPSY:
- NO MALIGNANCY IDENTIFIED.
- K. LYMPH NODES, LEVEL 5, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES (0/4).
- L. LYMPH NODE, 12L, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- M. LUNG, LEFT UPPER LOBE, LOBECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.
- 7.2 X 5.6 X 4.5 CM.
- THE SURFACE OF THE VISCERAL PLEURA IS NEGATIVE FOR TUMOR
-

[page 5 of 5]
-
- THE BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR.
- NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- NO PERINEURAL INVASION IDENTIFIED.
- SQUAMOUS CELLS CARCINOMA *IN-SITU* ARISING IN ASSOCIATION WITH A BRONCHUS.
- THE NON-NEOPLASTIC LUNG SHOWS EMPHYSEMATOUS CHANGES AND SUBPLEURAL FIBROSIS
- NO MALIGNANCY IDENTIFIED IN ELEVEN PERIBRONCHIAL LYMPH NODES (0/11).

N. LYMPH NODE, LEVEL 6, BIOPSY:

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES (0/2).

O. LYMPH NODES, LEVEL 9, BIOPSY;

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES (0/6).

Lung template

1. Tumor type: Squamous cell carcinoma
2. Histologic grade: Moderately differentiated
3. Tumor location: Peripheral
4. Tumor size: 7.2 x 5.6 x 4.5 cm.
5. Angiolymphatic invasion: Absent
6. Perineural invasion: Absent
7. Involvement of main stem bronchus: NA
8. Bronchial margin: Negative
9. Visceral pleural margin: Negative
10. Lymph nodes: Negative (0/33)
11. In-situ carcinoma: Present
12. Pathologic stage: pT2 N0
13. Non-neoplastic lung: Emphysema, subpleural fibrosis
-

Source: NCI Genomic Data Commons file be049627-7742-4696-b76a-8b5de1752922 (TCGA-60-2707.C3E54948-6849-4BAC-B04B-3E1A196E866B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).